Somatic mutation profile of tumor specimen TCGA-VR-AA7D-01A (aliquot TCGA-VR-AA7D-01A-11D-A403-09) from TCGA case TCGA-VR-AA7D, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 58.8 years (21,468 days).
Specimen TCGA-VR-AA7D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec838514-89bf-4a86-bdcc-e27cf734d80d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-AA7D-10A (Blood Derived Normal), aliquot TCGA-VR-AA7D-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9e0bc27-4dd8-4dea-9314-a67099c7b861

The open-access MAF lists 106 somatic variants for this specimen: 79 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 25, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 2, Splice Region 2, Intron 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD8 | c.4611del p.V1538* (on ENST00000646647 / NM_001170629.2; = p.V1259* on NM_020920.4) | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | catalogued as rs1555314317; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CREBBP | c.4337G>T p.R1446L | Missense Mutation (SNP) | VAF 43/128 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 34/65 reads (52%) | hotspot (GDC flag); catalogued as rs377767360, CM000742, COSV61685033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 31/37 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGAP4 | c.1879G>T p.V627F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as COSV71164803; called by mutect2, varscan2
- ASL | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564735357, COSV100508833; called by muse, mutect2, varscan2
- ATP13A1 | c.2611G>T p.A871S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1026495705; called by muse, mutect2, varscan2
- C5orf46 | c.72C>G p.D24E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs753733525, COSV100568473; called by muse, mutect2, varscan2
- CNOT3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55360792; called by muse, mutect2
- FAM234B | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52198369; called by muse, mutect2, varscan2
- FAM3D | c.145+1G>A p.X49_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as rs1375763301; called by muse, mutect2, varscan2
- FREM2 | c.2392C>G p.R798G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs922421314; called by muse, mutect2, varscan2
- GNAS | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as COSV55686667; called by muse, mutect2, varscan2
- KLK5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1568528155; called by muse, mutect2, varscan2
- KMT2A | c.11795G>A p.R3932H | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100630313, COSV63289059; called by muse, mutect2, varscan2
- KRI1 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs955008912; called by muse, mutect2, varscan2
- MRGPRF | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs918732602; called by muse, mutect2
- MRPL57 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV53436700; called by muse, mutect2, varscan2
- NEFH | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as rs756952361, COSV60214909; called by muse, mutect2, varscan2
- NOTCH3 | c.2647C>T p.R883* | Nonsense Mutation (SNP) | VAF 55/164 reads (34%) | catalogued as COSV54637031; called by muse, mutect2, varscan2
- NT5C1B | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as rs776002305, COSV100410203, COSV58395502; called by muse, varscan2
- OBSCN | c.21701C>T p.S7234L | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs776508320; called by muse, mutect2, varscan2
- PAXX | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs370085766; called by muse, mutect2, varscan2
- PLEKHG3 | c.616A>C p.M206L (on ENST00000394691; = p.M262L on NM_001308147.2) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV55984498; called by muse, mutect2, varscan2
- PPP2R1A | c.1366T>C p.Y456H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as rs746735616; called by muse, mutect2, varscan2
- PRTN3 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1214318289; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1118C>A p.P373Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54572475; called by muse, mutect2, varscan2
- RAPSN | c.1009C>A p.R337S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs549232026; called by muse, mutect2, varscan2
- SEPTIN12 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs758246500; called by muse, mutect2, varscan2
- SETD2 | c.6452C>T p.P2151L | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV57452612; called by muse, mutect2, varscan2
- SLC17A6 | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV54141833; called by muse, mutect2, varscan2
- SNTG1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as rs150099561; called by muse, mutect2, varscan2
- SOAT2 | c.138G>A p.E46= | Splice Region (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100037184; called by muse, mutect2, varscan2
- SOCS1 | c.608A>C p.Y203S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV59659715; called by muse, mutect2, varscan2
- TAGAP | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1433486337; called by muse, mutect2, varscan2
- TRAF1 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753124357; called by muse, mutect2, varscan2
- UTP20 | c.3580G>C p.E1194Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55372031; called by muse, mutect2
- ZCCHC24 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.972); catalogued as rs141500674, COSV100959251; called by muse, mutect2, varscan2
- ZNF493 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100828692, COSV62749145; called by muse, mutect2, varscan2
- AADACL4 | c.322T>A p.S108T | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- AC098582.1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AIG1 | c.168C>G p.I56M | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- AVIL | c.563del p.M188Sfs*18 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | called by mutect2, varscan2
- CNST | c.581A>G p.H194R | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNALI1 | c.283C>A p.L95I (on ENST00000296218; = p.L73I on NM_003462.5) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); called by muse, mutect2
- DOC2A | c.493A>T p.I165F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EEF2 | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPN1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GON4L | c.2543A>T p.N848I | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GRAMD4 | c.1349_1364del p.I450Kfs*59 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- HERC1 | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
- HGS | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- IER5 | c.143T>A p.L48Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ISG20 | c.321C>G p.I107M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- KMT2C | c.6343G>T p.A2115S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KRT6A | c.1648A>C p.K550Q | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2
- LGR6 | c.2141C>T p.S714F (on ENST00000367278 / NM_001017403.1; = p.S662F on NM_021636.3) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MYH7B | c.623-1G>C p.X208_splice | Splice Site (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- NARF | c.1250A>T p.H417L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- NIBAN1 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- NPEPPS | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NPHP3 | c.2142dup p.V715Cfs*19 | Frame Shift Ins (INS) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- NSMAF | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OR2F2 | c.218A>T p.Y73F | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- OR4S2 | c.349del p.A117Pfs*15 | Frame Shift Del (DEL) | VAF 23/36 reads (64%) | called by mutect2, pindel, varscan2
- PDS5B | c.2389C>T p.L797F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PIGB | c.555G>T p.W185C | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PYGB | c.2402A>G p.K801R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RICTOR | c.4619T>A p.I1540K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNF39 | c.570T>C p.D190= | Splice Region (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.656G>C p.R219T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SGTB | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SZT2 | c.2690A>T p.E897V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TCF7L1 | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- TRIM17 | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- TRIP4 | c.659C>G p.S220* | Nonsense Mutation (SNP) | VAF 64/167 reads (38%) | called by muse, mutect2, varscan2
- TUBB6 | c.350T>G p.L117R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VPS13C | c.8417A>T p.K2806M (on ENST00000644861 / NM_020821.3; = p.K2763M on NM_017684.5) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF766 | c.1192C>A p.L398I | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ADTRP | c.180C>A p.V60= | Silent (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- AURKA | c.354G>A p.Q118= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV57168440; called by muse, mutect2, varscan2
- CCDC141 | c.2055G>A p.A685= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs1353151648, COSV99836437; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5136G>C p.L1712= | Silent (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- COL13A1 | c.1041G>A p.G347= (on ENST00000398978 / NM_001130103.2; = p.G290= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100637421; called by muse, mutect2, varscan2
- CROCC | c.1167C>T p.D389= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as rs1182529549, COSV65013869; called by muse, mutect2, varscan2
- DCAF12L1 | c.594C>T p.F198= | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as COSV64421793; called by muse, mutect2, varscan2
- FGF5 | c.219C>T p.G73= | Silent (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- HS6ST3 | c.1182C>T p.R394= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- IFNGR2 | c.90G>T p.L30= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV51638079; called by muse, mutect2, varscan2
- KLHDC2 | c.387G>A p.V129= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs773736420; called by muse, mutect2, varscan2
- KMT2B | c.2166C>T p.H722= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs368953229; called by muse, mutect2, varscan2
- LRIG1 | c.1608C>T p.V536= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs770509956; called by muse, mutect2, varscan2
- NR2E1 | c.492C>A p.P164= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, varscan2
- OR5T1 | c.285C>A p.V95= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV57304302; called by muse, mutect2, varscan2
- OR6S1 | c.348G>A p.L116= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- OVCH1 | c.1623A>G p.P541= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- PKP2 | c.1725G>A p.A575= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs760093803, COSV50734612, COSV50754255; called by muse, mutect2, varscan2
- PPHLN1 | c.552A>G p.E184= | Silent (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.516G>A p.Q172= | Silent (SNP) | VAF 114/365 reads (31%) | called by muse, mutect2, varscan2
- PTPRM | c.3399G>A p.R1133= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100155611; called by muse, mutect2, varscan2
- RP1L1 | c.2766G>T p.L922= | Silent (SNP) | VAF 43/71 reads (61%) | called by muse, mutect2, varscan2
- TMC5 | c.1338C>T p.V446= (on ENST00000396229 / NM_001105248.1; = p.V200= on NM_024780.5) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV54909749; called by muse, mutect2, varscan2
- TUBB6 | c.351G>T p.L117= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs759576039; called by muse, mutect2, varscan2
- ZNFX1 | c.3465C>T p.T1155= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1323829615; called by muse, mutect2, varscan2
- CST1 | c.*1G>A | 3'UTR (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100494333; called by muse, mutect2, varscan2
- KALRN | c.5176+21734T>C | Intron (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
